Somatic mutation profile of cancer-model specimen HCM-SANG-0278-C20-85A (3D Organoid; aliquot HCM-SANG-0278-C20-85A-01D-A79M-36), derived from the primary tumor of HCMI case HCM-SANG-0278-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; Tumor grade: G2.
Specimen HCM-SANG-0278-C20-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d22981ab-95a4-46c9-9c7f-78e980d7b337.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0278-C20-10A (Blood Derived Normal), aliquot HCM-SANG-0278-C20-10A-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c4aa07e4-0e7a-4386-8adf-4b05b8e0f853

The open-access MAF lists 217 somatic variants for this specimen: 164 protein-altering or splice-affecting, 42 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 141, Silent 42, Frame Shift Ins 8, Nonsense Mutation 7, Intron 7, Frame Shift Del 3, Splice Region 3, Splice Site 2, RNA 2, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.1184G>A p.R395H | Missense Mutation (SNP) | VAF 138/275 reads (50%) | hotspot (GDC flag); SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs769910087, COSV66557504; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APC | c.1690C>T p.R564* | Nonsense Mutation (SNP) | VAF 64/64 reads (100%) | hotspot (GDC flag); catalogued as rs137854574, CM920035, COSV57321509; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARAF | c.641C>T p.S214F | Missense Mutation (SNP) | VAF 745/745 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs1057519786, COSV51691446, COSV51693647, COSV51695114; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MYO7A | c.689C>T p.A230V | Missense Mutation (SNP) | VAF 536/1136 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs797044512, CM065333; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.427G>A p.V143M | Missense Mutation (SNP) | VAF 563/564 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs587782620, CM132087, COSV52665025, COSV53025766, COSV53135444, COSV53176166; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADAM22 | c.2270C>T p.A757V | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.059); catalogued as rs773391403, COSV55975554; called by muse, mutect2, varscan2
- ADAMTS12 | c.3958G>A p.G1320R | Missense Mutation (SNP) | VAF 144/432 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs772207271, COSV61263569; called by muse, mutect2, varscan2
- ALDH1L1 | c.797C>G p.A266G | Missense Mutation (SNP) | VAF 383/902 reads (42%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.071); catalogued as COSV56416645; called by muse, mutect2, varscan2
- AOPEP | c.850T>C p.C284R | Missense Mutation (SNP) | VAF 107/412 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52921856; called by muse, mutect2, varscan2
- ARHGEF7 | c.2095G>A p.A699T (on ENST00000375741 / NM_001113511.2; = p.A521T on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/658 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as rs760012676; called by muse, mutect2
- C10orf90 | c.1731A>C p.E577D | Missense Mutation (SNP) | VAF 66/266 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52953509; called by muse, mutect2, varscan2
- CNTNAP2 | c.1999G>A p.A667T | Missense Mutation (SNP) | VAF 118/296 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.059); catalogued as rs374920791; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A3 | c.9352G>A p.E3118K | Missense Mutation (SNP) | VAF 75/157 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.137); catalogued as rs755613566, COSV55082509; called by muse, mutect2, varscan2
- DCHS1 | c.2152G>A p.G718R | Missense Mutation (SNP) | VAF 372/744 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs927596271; called by muse, mutect2, varscan2
- DDX53 | c.1727C>T p.S576L | Missense Mutation (SNP) | VAF 70/169 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.023); catalogued as rs1353262448, COSV100029045, COSV60069952; called by muse, mutect2, varscan2
- DNAH7 | c.6531G>T p.L2177F | Missense Mutation (SNP) | VAF 46/149 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV56757659; called by muse, mutect2, varscan2
- DNAJB2 | c.444C>T p.S148= | Splice Region (SNP) | VAF 213/530 reads (40%) | catalogued as rs200554674; called by muse, mutect2, varscan2
- ELAVL4 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 166/168 reads (99%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV63914167; called by muse, mutect2, varscan2
- EPB41L4B | c.2338C>T p.R780C | Missense Mutation (SNP) | VAF 248/583 reads (43%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); catalogued as rs769680131; called by muse, mutect2, varscan2
- ESF1 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 74/341 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.142); catalogued as rs895318507, COSV52522575; called by muse, mutect2, varscan2
- EXTL3 | c.53C>A p.T18N | Missense Mutation (SNP) | VAF 479/995 reads (48%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.043); catalogued as rs760747700; called by muse, mutect2, varscan2
- FAM187A | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 263/424 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as rs756050213; called by muse, mutect2, varscan2
- FAT3 | c.2218C>G p.P740A | Missense Mutation (SNP) | VAF 71/170 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV53117945; called by muse, mutect2, varscan2
- FREM1 | c.828+1G>A p.X276_splice | Splice Site (SNP) | VAF 73/146 reads (50%) | catalogued as rs745459062; called by muse, mutect2, varscan2
- GLI2 | c.3169G>A p.A1057T (on ENST00000361492 / NM_001374353.1; = p.A1074T on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 798/1613 reads (49%) | SIFT tolerated (0.47); PolyPhen benign (0.01); catalogued as COSV58036940; called by muse, mutect2, varscan2
- HECW1 | c.1733C>T p.A578V | Missense Mutation (SNP) | VAF 240/1113 reads (22%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.017); catalogued as rs770163676, COSV67842048; called by muse, mutect2, varscan2
- HEPACAM2 | c.1193C>T p.T398I (on ENST00000394468 / NM_001039372.4; = p.T386I on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs748934771; called by muse, mutect2, varscan2
- IL33 | c.615C>T p.L205= | Splice Region (SNP) | VAF 44/85 reads (52%) | catalogued as rs748541003, COSV67343658; called by muse, mutect2, varscan2
- KCNT2 | c.2989C>T p.R997C | Missense Mutation (SNP) | VAF 302/604 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.443); catalogued as rs750292796, COSV54100127; called by muse, mutect2, varscan2
- LASP1 | c.457C>T p.R153W | Missense Mutation (SNP) | VAF 678/1091 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as rs372318670; called by muse, mutect2
- LPO | c.157C>T p.R53* | Nonsense Mutation (SNP) | VAF 152/251 reads (61%) | catalogued as rs199842558; called by muse, mutect2, varscan2
- MAFG | c.5C>G p.T2R | Missense Mutation (SNP) | VAF 250/818 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.75); catalogued as COSV60814962; called by muse, varscan2
- MMP9 | c.1354C>T p.R452W | Missense Mutation (SNP) | VAF 850/1756 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.23); catalogued as rs368282794; called by muse, mutect2, varscan2
- NFKBIE | c.203G>C p.R68P | Missense Mutation (SNP) | VAF 440/1910 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1029766238; called by muse, mutect2, varscan2
- NLK | c.576del p.F192Lfs*30 | Frame Shift Del (DEL) | VAF 20/115 reads (17%) | catalogued as COSV69407880; called by mutect2, pindel, varscan2
- OR10J1 | c.122G>C p.G41A | Missense Mutation (SNP) | VAF 49/358 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.521); catalogued as COSV71129449; called by muse, mutect2, varscan2
- PAPLN | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 692/695 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as rs755902550, COSV53718275, COSV53721003; called by muse, varscan2
- PARP1 | c.2290A>G p.M764V | Missense Mutation (SNP) | VAF 224/380 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs771470250; called by muse, mutect2, varscan2
- PARP12 | c.841C>T p.R281W | Missense Mutation (SNP) | VAF 95/196 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs191980703, COSV54933651; called by muse, mutect2, varscan2
- PIK3R1 | c.2094C>A p.Y698* (on ENST00000521381 / NM_181523.3; = p.Y428* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 122/122 reads (100%) | catalogued as COSV57128526; called by muse, mutect2, varscan2
- PTEN | c.106G>A p.G36R | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as CM004280, CM124222, COSV100909550, COSV64289957, COSV64297290; called by muse, mutect2, varscan2
- PTH2R | c.411G>T p.K137N | Missense Mutation (SNP) | VAF 50/83 reads (60%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.468); catalogued as COSV55918915; called by muse, mutect2, varscan2
- RNF8 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 68/146 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.325); catalogued as rs769385134, COSV57721078; called by muse, mutect2, varscan2
- SCARA5 | c.673G>A p.G225S | Missense Mutation (SNP) | VAF 566/1150 reads (49%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.999); catalogued as rs773110333, COSV57280159; called by muse, mutect2, varscan2
- SCFD2 | c.1070T>C p.M357T | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as rs749551840; called by muse, mutect2, varscan2
- SCN10A | c.4774G>C p.G1592R | Missense Mutation (SNP) | VAF 354/842 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV71860409; called by muse, mutect2, varscan2
- SDK2 | c.1105G>A p.G369S | Missense Mutation (SNP) | VAF 389/1089 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs774180082; called by muse, mutect2, varscan2
- SEC23IP | c.2837G>A p.R946H | Missense Mutation (SNP) | VAF 44/251 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.427); catalogued as rs763678111, COSV100956806, COSV64833143; called by muse, mutect2, varscan2
- SEMA6B | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 416/716 reads (58%) | SIFT tolerated (0.33); PolyPhen benign (0.121); catalogued as rs758790120; called by muse, mutect2, varscan2
- SMARCA4 | c.2344G>C p.G782R | Missense Mutation (SNP) | VAF 323/872 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100759205, COSV60801274; called by muse, mutect2, varscan2
- SPAG4 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 430/2458 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.985); catalogued as COSV65330450; called by muse, mutect2, varscan2
- TJP1 | c.4610G>A p.R1537Q | Missense Mutation (SNP) | VAF 120/284 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.59); catalogued as rs374164533; called by muse, mutect2, varscan2
- TMEM25 | c.829A>G p.I277V | Missense Mutation (SNP) | VAF 327/680 reads (48%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1427238206; called by muse, mutect2, varscan2
- TRAPPC6A | c.445G>A p.V149I (on ENST00000585934 / NM_001270891.2; = p.V163I on NM_024108.3) | Missense Mutation (SNP) | VAF 342/620 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs777403161; called by muse, mutect2, varscan2
- TTC30A | c.1172G>A p.R391Q | Missense Mutation (SNP) | VAF 130/242 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs376383604; called by muse, mutect2, varscan2
- TTN | c.47080C>T p.R15694C (on ENST00000591111; = p.R8270C on NM_003319.4) | Missense Mutation (SNP) | VAF 89/186 reads (48%) | PolyPhen benign (0); catalogued as rs763755830, COSV60177959; called by muse, mutect2, varscan2
- VSIG10L2 | c.2014C>T p.L672F | Missense Mutation (SNP) | VAF 531/1092 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs1178626022; called by muse, mutect2, varscan2
- WIPI2 | c.779G>T p.G260V | Missense Mutation (SNP) | VAF 148/827 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as COSV56589229; called by muse, mutect2, varscan2
- ZNF229 | c.433G>A p.G145R | Missense Mutation (SNP) | VAF 74/160 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as rs1568403079, COSV99350212, COSV99351188; called by muse, varscan2
- ADAMTS20 | c.2170A>C p.T724P | Missense Mutation (SNP) | VAF 14/167 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2
- ADGRA1 | c.896G>C p.G299A | Missense Mutation (SNP) | VAF 836/1558 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2
- ANKRD33B | c.872T>C p.L291P | Missense Mutation (SNP) | VAF 646/1863 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- ANTXRL | c.703G>A p.G235S | Missense Mutation (SNP) | VAF 145/294 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- ARHGEF18 | c.2340G>C p.E780D (on ENST00000359920 / NM_001130955.2; = p.E676D on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/1281 reads (3%) | SIFT tolerated (0.18); PolyPhen benign (0.012); called by muse, mutect2
- ATL2 | c.459G>C p.W153C | Missense Mutation (SNP) | VAF 44/173 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATRN | c.223C>G p.L75V | Missense Mutation (SNP) | VAF 1169/2406 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, varscan2
- BNIP5 | c.1605G>A p.K535= | Splice Region (SNP) | VAF 229/453 reads (51%) | called by muse, mutect2, varscan2
- BPIFB6 | c.785T>G p.F262C | Missense Mutation (SNP) | VAF 115/1160 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- C7orf25 | c.395T>A p.L132Q | Missense Mutation (SNP) | VAF 144/259 reads (56%) | SIFT tolerated (0.74); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- C8orf76 | c.495G>A p.W165* | Nonsense Mutation (SNP) | VAF 56/227 reads (25%) | called by muse, mutect2, varscan2
- CACNA1B | c.3347T>C p.V1116A | Missense Mutation (SNP) | VAF 539/1055 reads (51%) | SIFT tolerated (0.74); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CBLL2 | c.88_89insC p.K30Tfs*13 | Frame Shift Ins (INS) | VAF 94/131 reads (72%) | called by mutect2, pindel, varscan2
- CBLN4 | c.127G>T p.V43L | Missense Mutation (SNP) | VAF 1094/2204 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- CD8A | c.295G>A p.V99I | Missense Mutation (SNP) | VAF 480/991 reads (48%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH9 | c.263T>C p.L88S | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- CENPE | c.3362G>C p.R1121T | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- CLSTN3 | c.2665G>A p.D889N | Missense Mutation (SNP) | VAF 285/1138 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNNM3 | c.230C>G p.S77C | Missense Mutation (SNP) | VAF 431/1567 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- CP | c.2458G>C p.V820L | Missense Mutation (SNP) | VAF 85/209 reads (41%) | SIFT tolerated (0.73); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- CPA1 | c.946T>G p.Y316D | Missense Mutation (SNP) | VAF 129/553 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSF2RA | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 452/509 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CYP4Z1 | c.92G>A p.R31K | Missense Mutation (SNP) | VAF 38/364 reads (10%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2
- DCDC1 | c.1221G>T p.Q407H | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- DNAH6 | c.7301G>C p.R2434P | Missense Mutation (SNP) | VAF 65/308 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DUSP2 | c.137C>A p.A46E | Missense Mutation (SNP) | VAF 827/1602 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- EDAR | c.1065G>C p.K355N | Missense Mutation (SNP) | VAF 154/527 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- EPB41L3 | c.2910T>G p.I970M | Missense Mutation (SNP) | VAF 78/145 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- ETS2 | c.711G>C p.Q237H | Missense Mutation (SNP) | VAF 351/551 reads (64%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM172A | c.1240G>T p.E414* | Nonsense Mutation (SNP) | VAF 194/446 reads (43%) | called by muse, mutect2, varscan2
- FAT2 | c.6607C>G p.L2203V | Missense Mutation (SNP) | VAF 38/426 reads (9%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.998); called by muse, mutect2
- FAT4 | c.7024C>A p.P2342T | Missense Mutation (SNP) | VAF 56/79 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FBXO21 | c.1709A>G p.Y570C (on ENST00000330622 / NM_033624.3; = p.Y563C on NM_015002.3) | Missense Mutation (SNP) | VAF 51/185 reads (28%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- FBXO33 | c.47G>C p.R16P | Missense Mutation (SNP) | VAF 671/671 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- FLG | c.3928G>C p.G1310R | Missense Mutation (SNP) | VAF 230/474 reads (49%) | SIFT tolerated (0.45); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- FMO4 | c.949G>C p.V317L | Missense Mutation (SNP) | VAF 46/220 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- FRMPD1 | c.1675C>T p.P559S | Missense Mutation (SNP) | VAF 461/923 reads (50%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- GJA5 | c.849C>A p.F283L | Missense Mutation (SNP) | VAF 498/771 reads (65%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- GLB1L2 | c.444G>T p.L148F | Missense Mutation (SNP) | VAF 90/1169 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); called by muse, mutect2
- GLB1L3 | c.522G>T p.L174F | Missense Mutation (SNP) | VAF 236/611 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- GON4L | c.2120T>C p.L707P | Missense Mutation (SNP) | VAF 55/252 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPNMB | c.527T>C p.V176A | Missense Mutation (SNP) | VAF 135/258 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- GPR22 | c.1255A>G p.S419G | Missense Mutation (SNP) | VAF 53/102 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GREB1 | c.5670G>C p.K1890N | Missense Mutation (SNP) | VAF 112/250 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- GSTA4 | c.431G>A p.G144E | Missense Mutation (SNP) | VAF 13/162 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.604); called by muse, mutect2
- H1-5 | c.671A>C p.K224T | Missense Mutation (SNP) | VAF 75/369 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- HELB | c.691_695dup p.I233Gfs*3 | Frame Shift Ins (INS) | VAF 59/138 reads (43%) | called by mutect2, pindel, varscan2
- HELQ | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 267/395 reads (68%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- HERC1 | c.3142_3145dup p.K1049Rfs*21 | Frame Shift Ins (INS) | VAF 34/107 reads (32%) | called by mutect2, pindel, varscan2
- HMGCL | c.199G>A p.G67R | Missense Mutation (SNP) | VAF 93/95 reads (98%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HYI | c.842_843del p.T281Sfs*13 (on ENST00000372434 / NM_001330526.2; = p.T256Sfs*13 on NM_001190880.2) | Frame Shift Del (DEL) | VAF 650/1750 reads (37%) | called by pindel, varscan2
- IL17A | c.386G>A p.C129Y | Missense Mutation (SNP) | VAF 452/950 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KBTBD11 | c.1189C>T p.P397S | Missense Mutation (SNP) | VAF 643/1266 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- KCNG3 | c.1031T>A p.L344H | Missense Mutation (SNP) | VAF 51/294 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNT2 | c.2653_2657delinsTTA p.G885Lfs*4 | Frame Shift Del (DEL) | VAF 43/211 reads (20%) | called by pindel, varscan2*
- KDR | c.2848G>C p.D950H | Missense Mutation (SNP) | VAF 137/200 reads (69%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- LIPJ | c.489_490insG p.F164Vfs*19 | Frame Shift Ins (INS) | VAF 16/82 reads (20%) | called by mutect2, pindel, varscan2
- LRCH1 | c.622G>T p.G208C | Missense Mutation (SNP) | VAF 92/227 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- LRGUK | c.617C>A p.S206Y | Missense Mutation (SNP) | VAF 9/193 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.679); called by muse, mutect2
- MAP9 | c.1733_1734insC p.K578Nfs*4 | Frame Shift Ins (INS) | VAF 8/41 reads (20%) | called by mutect2, pindel, varscan2
- MARS2 | c.1142A>G p.N381S | Missense Mutation (SNP) | VAF 277/529 reads (52%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- MTMR12 | c.1112A>T p.K371I | Missense Mutation (SNP) | VAF 24/183 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- NCEH1 | c.697G>A p.G233S (on ENST00000538775; = p.G193S on NM_020792.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 105/405 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NFX1 | c.2872A>T p.K958* | Nonsense Mutation (SNP) | VAF 74/196 reads (38%) | called by muse, mutect2, varscan2
- NOMO1 | c.3407G>A p.G1136D | Missense Mutation (SNP) | VAF 101/210 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- OR2L2 | c.184C>T p.L62F | Missense Mutation (SNP) | VAF 71/202 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR5AP2 | c.948G>T p.L316F | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- OVCA2 | c.91A>G p.K31E | Missense Mutation (SNP) | VAF 497/986 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PALD1 | c.353G>C p.C118S | Missense Mutation (SNP) | VAF 268/1148 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- PEX2 | c.591G>A p.W197* | Nonsense Mutation (SNP) | VAF 39/173 reads (23%) | called by muse, mutect2, varscan2
- PIK3C2B | c.1118G>T p.G373V | Missense Mutation (SNP) | VAF 204/520 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PILRA | c.200T>A p.V67E | Missense Mutation (SNP) | VAF 141/1016 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- PKHD1L1 | c.10255A>T p.T3419S | Missense Mutation (SNP) | VAF 54/115 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- PLEC | c.703C>T p.H235Y (on ENST00000322810 / NM_201380.4; = p.H125Y on NM_000445.5) | Missense Mutation (SNP) | VAF 563/1205 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PRELID3B | c.241C>T p.H81Y | Missense Mutation (SNP) | VAF 26/191 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.026); called by muse, varscan2
- QSER1 | c.1777dup p.Q593Pfs*6 (on ENST00000399302; = p.Q722Pfs*6 on NM_001076786.3) | Frame Shift Ins (INS) | VAF 18/117 reads (15%) | called by mutect2, pindel, varscan2
- RNF133 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 75/183 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- RPL11 | c.135G>C p.Q45H (on ENST00000374550 / NM_001199802.1; = p.Q46H on NM_000975.5) | Missense Mutation (SNP) | VAF 103/204 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- RTTN | c.418A>C p.I140L | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCAF8 | c.2383A>G p.N795D | Missense Mutation (SNP) | VAF 57/121 reads (47%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- SCRN3 | c.542-1G>C p.X181_splice | Splice Site (SNP) | VAF 13/88 reads (15%) | called by muse, mutect2, varscan2
- SFMBT1 | c.178G>A p.V60M | Missense Mutation (SNP) | VAF 84/314 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- SH3BP4 | c.2635C>T p.H879Y | Missense Mutation (SNP) | VAF 118/1258 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2
- SHROOM2 | c.2362G>A p.E788K | Missense Mutation (SNP) | VAF 635/636 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- SLC16A14 | c.269T>G p.I90S | Missense Mutation (SNP) | VAF 81/333 reads (24%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- SLC25A52 | c.742C>T p.R248C (on ENST00000672005; = p.R238C on NM_001034172.4) | Missense Mutation (SNP) | VAF 67/67 reads (100%) | SIFT tolerated (0.08); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- SLC35F1 | c.646A>G p.K216E | Missense Mutation (SNP) | VAF 55/110 reads (50%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- SMARCAL1 | c.2550T>G p.I850M | Missense Mutation (SNP) | VAF 35/191 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- STARD13 | c.2415G>C p.M805I (on ENST00000336934 / NM_001243476.3; = p.M687I on NM_052851.3) | Missense Mutation (SNP) | VAF 144/803 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYAP1 | c.709G>C p.D237H | Missense Mutation (SNP) | VAF 106/483 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- SYNM | c.2175G>A p.M725I | Missense Mutation (SNP) | VAF 268/803 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- SYT9 | c.1216A>G p.R406G | Missense Mutation (SNP) | VAF 133/287 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- TCF7L2 | c.1207G>A p.A403T (on ENST00000355995 / NM_001367943.1; = p.A380T on NM_030756.5) | Missense Mutation (SNP) | VAF 294/613 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM245 | c.1174A>T p.I392F | Missense Mutation (SNP) | VAF 99/409 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- TOGARAM1 | c.242G>T p.S81I | Missense Mutation (SNP) | VAF 279/838 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- TRNT1 | c.592dup p.I198Nfs*17 | Frame Shift Ins (INS) | VAF 29/69 reads (42%) | called by mutect2, pindel, varscan2
- TTN | c.60774dup p.D20259Rfs*40 (on ENST00000591111; = p.D12835Rfs*40 on NM_003319.4) | Frame Shift Ins (INS) | VAF 86/269 reads (32%) | called by mutect2, pindel, varscan2
- TTN | c.50062A>C p.I16688L (on ENST00000591111; = p.I9264L on NM_003319.4) | Missense Mutation (SNP) | VAF 94/172 reads (55%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- WDR82 | c.328G>A p.V110M | Missense Mutation (SNP) | VAF 82/156 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF292 | c.3809G>C p.S1270T | Missense Mutation (SNP) | VAF 43/199 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ZNF385A | c.341A>T p.E114V (on ENST00000338010 / NM_001130967.3; = p.E94V on NM_015481.3) | Missense Mutation (SNP) | VAF 605/1191 reads (51%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ZNF573 | c.1060G>T p.G354C (on ENST00000536220 / NM_001172692.1; = p.G296C on NM_152360.3) | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.068); called by muse, mutect2
- ZNF577 | c.1217A>T p.E406V | Missense Mutation (SNP) | VAF 112/192 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF626 | c.912G>C p.K304N | Missense Mutation (SNP) | VAF 58/116 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, varscan2
- ZNF85 | c.1267G>C p.E423Q | Missense Mutation (SNP) | VAF 64/117 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- AC098582.1 | c.591C>T p.A197= | Silent (SNP) | VAF 188/602 reads (31%) | catalogued as rs375133122; called by muse, varscan2
- AGXT2 | c.96T>A p.T32= | Silent (SNP) | VAF 61/223 reads (27%) | catalogued as rs1376639365; called by muse, mutect2, varscan2
- ARHGAP45 | c.1137G>A p.K379= | Silent (SNP) | VAF 446/743 reads (60%) | called by muse, mutect2, varscan2
- BECN2 | c.249G>T p.L83= | Silent (SNP) | VAF 709/1294 reads (55%) | called by muse, mutect2, varscan2
- CCDC39 | c.747A>C p.A249= | Silent (SNP) | VAF 21/114 reads (18%) | called by muse, mutect2, varscan2
- CEACAM4 | c.459C>T p.V153= | Silent (SNP) | VAF 416/1015 reads (41%) | catalogued as rs148761752; called by muse, mutect2, varscan2
- CTNND2 | c.1185C>T p.S395= | Silent (SNP) | VAF 207/674 reads (31%) | catalogued as COSV58870579; called by muse, mutect2, varscan2
- DCLRE1A | c.612C>T p.G204= | Silent (SNP) | VAF 127/217 reads (59%) | catalogued as rs369452771; called by muse, mutect2, varscan2
- DNAH11 | c.399T>A p.I133= | Silent (SNP) | VAF 68/111 reads (61%) | called by muse, mutect2, varscan2
- FAM166B | c.526C>A p.R176= | Silent (SNP) | VAF 354/743 reads (48%) | called by muse, mutect2, varscan2
- FBXW2 | c.1185G>A p.E395= | Silent (SNP) | VAF 45/545 reads (8%) | called by muse, mutect2
- GAA | c.1767G>A p.K589= | Silent (SNP) | VAF 313/933 reads (34%) | catalogued as COSV56409765; called by muse, mutect2, varscan2
- GIPC3 | c.1725C>A p.T575= | Silent (SNP) | VAF 245/392 reads (63%) | called by muse, mutect2, varscan2
- GLI2 | c.2277C>T p.G759= (on ENST00000361492 / NM_001374353.1; = p.G776= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 243/1082 reads (22%) | catalogued as rs571722810, COSV58042831, COSV58050095; called by muse, mutect2, varscan2
- GTF3C2 | c.1908G>T p.R636= | Silent (SNP) | VAF 117/238 reads (49%) | called by muse, mutect2, varscan2
- H2AW | c.108C>T p.R36= | Silent (SNP) | VAF 436/2203 reads (20%) | catalogued as rs770784546; called by muse, mutect2, varscan2
- HABP4 | c.957T>A p.P319= | Silent (SNP) | VAF 44/216 reads (20%) | called by muse, mutect2, varscan2
- HROB | c.1035A>G p.P345= | Silent (SNP) | VAF 131/442 reads (30%) | called by muse, mutect2, varscan2
- IMP4 | c.57G>A p.E19= | Silent (SNP) | VAF 313/1282 reads (24%) | called by muse, mutect2, varscan2
- ITGA4 | c.2748T>C p.H916= | Silent (SNP) | VAF 72/151 reads (48%) | catalogued as rs970767764; called by muse, mutect2, varscan2
- KCNJ4 | c.405C>T p.I135= | Silent (SNP) | VAF 641/1352 reads (47%) | catalogued as rs372930285; called by muse, mutect2, varscan2
- LRRC38 | c.480C>T p.N160= | Silent (SNP) | VAF 707/1547 reads (46%) | catalogued as rs1306770647, COSV65791564; called by muse, mutect2, varscan2
- MRGPRX1 | c.783C>T p.S261= | Silent (SNP) | VAF 168/388 reads (43%) | catalogued as rs755616556, COSV57106086; called by muse, varscan2
- MSANTD2 | c.9G>A p.A3= | Silent (SNP) | VAF 341/688 reads (50%) | catalogued as rs1311846668, COSV53448348; called by muse, mutect2, varscan2
- MYH15 | c.537C>G p.A179= | Silent (SNP) | VAF 82/258 reads (32%) | called by muse, mutect2, varscan2
- NR5A2 | c.577C>T p.L193= (on ENST00000367362 / NM_205860.3; = p.L147= on NM_003822.5) | Silent (SNP) | VAF 75/449 reads (17%) | called by muse, mutect2, varscan2
- NRCAM | c.1242C>T p.G414= (on ENST00000379028 / NM_001371124.1; = p.G408= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 52/117 reads (44%) | catalogued as rs746601628, COSV61032192; called by muse, mutect2, varscan2
- NRXN3 | c.633G>A p.A211= (on ENST00000557594 / NM_001272020.2; = p.A843= on NM_004796.6) | Silent (SNP) | VAF 37/161 reads (23%) | catalogued as rs527486862, COSV55365449; called by muse, mutect2, varscan2
- PAPPA2 | c.2487T>C p.Y829= | Silent (SNP) | VAF 234/399 reads (59%) | called by muse, mutect2, varscan2
- PCDH17 | c.1749C>A p.I583= | Silent (SNP) | VAF 262/1477 reads (18%) | catalogued as COSV64973897; called by muse, mutect2, varscan2
- PIN1 | c.291G>A p.K97= | Silent (SNP) | VAF 142/505 reads (28%) | called by muse, mutect2, varscan2
- PPFIBP2 | c.1464T>G p.P488= | Silent (SNP) | VAF 212/428 reads (50%) | called by muse, mutect2
- PZP | c.2370C>T p.A790= | Silent (SNP) | VAF 131/376 reads (35%) | called by muse, mutect2, varscan2
- SCN5A | c.3111C>A p.G1037= | Silent (SNP) | VAF 180/1506 reads (12%) | catalogued as rs1057521031; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCN7A | c.5016T>C p.A1672= | Silent (SNP) | VAF 69/160 reads (43%) | called by muse, mutect2, varscan2
- SDK1 | c.4086G>T p.G1362= | Silent (SNP) | VAF 558/1130 reads (49%) | catalogued as rs1264747229; called by muse, mutect2, varscan2
- SLC2A1 | c.111G>A p.Q37= | Silent (SNP) | VAF 107/562 reads (19%) | catalogued as COSV65286732; called by muse, mutect2, varscan2
- STC2 | c.273C>T p.N91= | Silent (SNP) | VAF 195/324 reads (60%) | catalogued as rs748039896; called by muse, mutect2, varscan2
- SUSD5 | c.657A>G p.S219= | Silent (SNP) | VAF 127/288 reads (44%) | catalogued as rs774367436; called by muse, mutect2, varscan2
- TRIM35 | c.1443C>T p.C481= | Silent (SNP) | VAF 192/769 reads (25%) | called by muse, mutect2, varscan2
- UTRN | c.4953G>A p.Q1651= | Silent (SNP) | VAF 16/84 reads (19%) | called by muse, mutect2, varscan2
- ZIC4 | c.342C>T p.G114= | Silent (SNP) | VAF 710/1466 reads (48%) | catalogued as COSV101267960; called by muse, mutect2, varscan2
- AC024598.1 | c.1130-830C>T | Intron (SNP) | VAF 94/371 reads (25%) | called by muse, mutect2, varscan2
- DCHS2 | n.3875A>G | RNA (SNP) | VAF 22/86 reads (26%) | called by muse, mutect2, varscan2
- FLVCR2 | c.670-16482C>G | Intron (SNP) | VAF 61/221 reads (28%) | called by muse, mutect2, varscan2
- LINP1 | n.391A>G | RNA (SNP) | VAF 276/478 reads (58%) | called by muse, mutect2, varscan2
- LMNTD1 | c.26+169G>A | Intron (SNP) | VAF 22/168 reads (13%) | called by muse, mutect2, varscan2
- PML | c.1710+1212C>T | Intron (SNP) | VAF 1003/1564 reads (64%) | catalogued as rs746195982; called by muse, mutect2, varscan2
- PRR12 | c.52-117dup | Intron (INS) | VAF 420/1003 reads (42%) | called by mutect2, varscan2
- RAD9B | c.*23C>G | 3'UTR (SNP) | VAF 52/164 reads (32%) | called by muse, mutect2, varscan2
- RNU6-1191P | chr16:81108598 G>A | 5'Flank (SNP) | VAF 102/176 reads (58%) | catalogued as rs375288405; called by muse, mutect2
- SHANK2 | c.2551+33C>A | Intron (SNP) | VAF 148/298 reads (50%) | catalogued as rs1555155404, COSV99571277; called by muse, mutect2, varscan2
- TM9SF1 | c.1427+12T>G | Intron (SNP) | VAF 236/238 reads (99%) | called by muse, mutect2, varscan2
